Gene-level copy-number profile of tumor specimen TCGA-60-2710-01A from TCGA case TCGA-60-2710, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 67.5 years (24,669 days).
Specimen TCGA-60-2710-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.2b428024-b947-49a5-8209-d17b9cec3cce.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-60-2710-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/04b2f0f9-2828-49eb-be29-43b388a5aaa8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 13,022; copy number 2: 39,021; copy number 3: 5,460; copy number 4: 404; copy number 5: 1,354; copy number 6: 550; copy number 10: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-60-2710-01A-01D-1969-01): tumor purity 0.65, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,906 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:89,587,886–198,222,513, 1,808 genes, copy number 5–6 (broad region; genes not listed).
- chr5:72,087,782–73,295,258, 30 genes, copy number 5: AC025774.1, MAP1B, MIR4803, MRPS27, RN7SL153P, PTCD2, AC093278.1, YBX1P5, AC093278.2, ZNF366, LINC02056, AC063979.1, RPL7P22, H2BL1P, Y_RNA, AC035140.1, TNPO1, MIR4804, RPL35AP13, AC008972.1, AC008972.2, FCHO2, AC020893.1, CHP1P1, TMEM171, AC116345.3, AC116345.2, TMEM174, AC116345.4, AC116345.1.
- chr9:25,937,912–26,118,408, 2 genes, copy number 10: FAM71BP1, AL353753.1.
- chr17:20,491,323–21,594,180, 66 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,022. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
